MMRF case MMRF_1644 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ce2364f6-fac4-43f2-9947-8c9d11c294a1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.3 years (30,775 days); ISS stage: III; Days to last known disease status: 66 days; Days to last follow up: 66 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 3): M Protein 2.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 758 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 43 mg/dL; Immunoglobulin G 23.3 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 7.4 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.65 mmol/L; Albumin 30 g/L; Total Protein 7 g/dL; Glucose 7.04 mmol/L; C-Reactive Protein 3.08 mg/dL.
- Day 66 (ECOG 3): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 8.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.73 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 10 mmol/L.

Other clinical attributes
- Day -20: Weight: 64 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1644_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1644_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
